CCDI case PBCDID — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Nasopharynx.
https://portal.gdc.cancer.gov/cases/e368b753-ac6a-4843-8eb4-a039dd8abfff

Demographics
Sex at birth: male.

Diagnoses (1)
1. Rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8900/3; Tissue or organ of origin: Maxillary sinus; Age at diagnosis: 14.4 years (5,273 days).

Biospecimens (3 samples)
- Sample 0DPSN1: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DPSNJ: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DPSNO: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
